FM case AD6570 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/722bbb41-0c8c-4575-99c7-d012f654f79e

Female, 61.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the cervix uteri; metastasis biopsied or resected from the uterus. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
